Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA2Q, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA2Q-01A (Primary Tumor).

Male

Surgery Date:

DIAGNOSIS:

Liver, left lobe, hepatectomy: Intrahepatic cholangiocarcinoma, grade 2 (of 4), is identified forming a multinodular, discrete, firm mass (12.3 x 11.5 x 10.0 cm) occupying the majority of the resected left hepatic lobe with extension to the attached caudate lobe. A single satellite tumor is identified in the dome of the liver and forms a 0.8 cm diameter tumor. The margins of resection are negative for tumor. The carcinoma is 0.1 cm from the parenchymal resection margin as well as 0.2 cm from the bile duct margin. The

hepatic vein and portal vein margins are negative for tumor. A single hilar lymph node is negative for tumor. The non-neoplastic liver will be assessed on permanent section and reported as an addendum.

Gallbladder, cholecystectomy: Mild chronic cholecystitis. No gallstones are identified. The pericyclic duct lymph node is negative for tumor.

Lymph nodes, hepatoduodenal, excision: Multiple (24) hepatoduodenal lymph nodes are negative for tumor.

Lymph nodes, para-aortic, excision: Multiple (3) para-aortic lymph nodes are negative for tumor.

ICD-O-3

Cholangiocarcinoma 8160/3

Site: Intrahepatic bile duct C22.1

Sp 3/8/14

Print: Malignancy History		☒

Source: NCI Genomic Data Commons file 7ac21b29-21ca-4bd5-9e2d-471fc6d8fb8b (TCGA-W5-AA2Q.ED7C4C0A-BBCE-4136-B95F-4E49DB17EEE3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).